TARGET case TARGET-15-SJMPAL043774 — Acute Lymphoblastic Leukemia - Phase III (TARGET-ALL-P3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/9d9197f4-2bcb-42d2-bbdd-0df95ab56e9c

Demographics
Sex at birth: male; Age at index: 0 years; Vital status: Dead; Days to death: 156 days.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 0.0 years (12 days); Year of diagnosis: 2002; Days to last follow up: 156 days.

Follow-up (1 entry)
- Days to follow up: 156 days; Event-free: no event (relapse, second malignancy or death) recorded through day 156; Year of follow up: 2003.

Molecular and laboratory tests (laboratory values one line per visit day)
- Day 0: Leukocytes 67 ×10³/µL.

Biospecimens (3 samples)
- Samples TARGET-15-SJMPAL043774-09A.1, TARGET-15-SJMPAL043774-09B (2 with the same recorded description): Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
- Sample TARGET-15-SJMPAL043774-14A.1: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_III_20230725.xlsx:
- Overall Survival Time in Days: 156
- Protocol: St. Jude
- WBC at Diagnosis: 67
- Initial Therapy: ALL
- Karyotype: 46,XY,t(9;11)(p13;q23)[18]/46,XY[2]
- WHO ALAL Classification: MLL
- WHO Dx: MLL
